Gene-level copy-number profile of tumor specimen TCGA-ER-A3ES-06A from TCGA case TCGA-ER-A3ES, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 45.5 years (16,605 days).
Specimen TCGA-ER-A3ES-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.86ab5d60-feec-4c60-a498-314335d58a09.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ER-A3ES-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/199570f4-f4ce-4ce4-a8c3-2dddc87ce559

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 4,798; copy number 2: 49,591; copy number 3: 3,576; copy number 4: 588; copy number 5: 1,238; copy number 6: 16; copy number 7: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ER-A3ES-06A-11D-A20B-01): tumor purity 0.99, ploidy 2.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,994,139–22,128,103, 5 genes (within-gene range 0–1): CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,255 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:190,878,145–200,483,604, 104 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:38,256,337–38,329,643, 12 genes, copy number 5: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2.
- chr8:123,563,070–145,066,685, 404 genes, copy number 5–6 (broad region; genes not listed).
- chr11:20,669,551–21,575,686, 1 gene, copy number 5 (within-gene range 4–7): NELL1.
- chr11:21,000,881–22,830,299, 19 genes, copy number 5–7: RNA5SP336, AC090857.1, AC090857.2, AC099730.1, RNA5SP337, AC130307.1, ANO5, AC116534.1, AC107882.1, AC107886.1, AC104009.1, SLC17A6, AC040936.1, LINC01495, AC055878.1, FANCF, GAS2, RNA5SP338, SVIP.
- chr11:22,846,922–22,860,474, 1 gene, copy number 5 (within-gene range 3–5): CCDC179.
- chr11:63,137,867–63,369,718, 1 gene, copy number 5 (within-gene range 3–5): SLC22A10.
- chr11:63,243,085–72,245,664, 442 genes, copy number 5 (broad region; genes not listed).
- chr11:72,836,745–73,142,318, 1 gene, copy number 5 (within-gene range 3–5): FCHSD2.
- chr11:73,157,946–79,441,030, 184 genes, copy number 5 (broad region; genes not listed).
- chr11:87,490,144–90,226,538, 86 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,416. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
